TCGA case TCGA-30-1869 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Harvard. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/84f5876d-82b0-45ff-8f3d-a10653683454

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Dead; Days to death: 1,563 days (4.3 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 50.4 years (18,398 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; FIGO stage: Stage IV; Tumor grade: G3; Prior treatment: No.
   Pathology details: Lymphatic invasion present: No; Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Days to treatment end: 179 days; Number of cycles: 9; Treatment dose: 5 AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Days to treatment end: 179 days; Number of cycles: 9; Treatment dose: 1,000 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Days to treatment end: 179 days; Number of cycles: 9; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 767 days (2.1 years); Days to treatment end: 943 days (2.6 years); Number of cycles: 8; Treatment dose: 400 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed Disodium; Initial disease status: Recurrent Disease; Days to treatment start: 767 days (2.1 years); Days to treatment end: 943 days (2.6 years); Number of cycles: 8; Treatment dose: 500 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 1,132 days (3.1 years); Days to treatment end: 1,175 days (3.2 years); Treatment dose: 30 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 1,184 days (3.2 years); Days to treatment end: 1,211 days (3.3 years); Treatment dose: 40 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vosaroxin; Initial disease status: Progressive Disease; Days to treatment start: 1,279 days (3.5 years); Days to treatment end: 1,331 days (3.6 years); Number of cycles: 2; Treatment dose: 48 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,398 days (3.8 years); Days to treatment end: 1,489 days (4.1 years); Number of cycles: 6; Treatment dose: 5 AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 1,398 days (3.8 years); Days to treatment end: 1,489 days (4.1 years); Number of cycles: 6; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 1,510 days (4.1 years); Days to treatment end: 1,534 days (4.2 years); Number of cycles: 3; Treatment dose: 3 mg/m2; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 52.5 years (19,165 days); Days to diagnosis: 767 days (2.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 767 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 767 days (2.1 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,563 days (4.3 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-30-1869-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
  Slide TCGA-30-1869-01A-01-TS1: Section location: Top; Percent tumor nuclei: 0; Percent necrosis: 0.
  Slide TCGA-30-1869-01A-01-BS1: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40.
- Sample TCGA-30-1869-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 5: Pharmaceutical therapy drug name: SNS 595; Therapy regimen: Progression.
- Drug treatment 6: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.
- Drug treatment 7: Pharmaceutical therapy drug name: Carbplatin; Therapy regimen: Progression.
- Drug treatment 10: Pharmaceutical therapy drug name: Alimta.
- Drug treatment 11: Pharmaceutical therapy drug name: Avastin.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

GDC annotations on this case (curator notes; quoted as recorded):
- Pathology outside specification: Pathology Results off Spec.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,563 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,563 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 767 days.
